Somatic mutation profile of tumor specimen 0DS6L3 from CCDI case PBCHKY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Subependymoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.1 years (7,346 days).
Specimen 0DS6L3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 489ff6e6-be48-431e-aec0-9d0ca34a0c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS6LH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a5ebcf6-6cce-46a1-a9fd-09de59650a8d

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRR12 | c.232G>A p.V78I (on ENST00000615927; = p.V899I on NM_020719.3) | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.236); catalogued as rs772679348; called by muse, mutect2
- AVIL | c.519A>G p.Q173= | Silent (SNP) | VAF 22/510 reads (4%) | called by muse, mutect2
- RBM47 | c.1071C>T p.Y357= | Silent (SNP) | VAF 21/489 reads (4%) | catalogued as rs910766279, COSV55929728; called by muse, mutect2
